Somatic mutation profile of tumor specimen TCGA-R6-A8W5-01B (aliquot TCGA-R6-A8W5-01B-11D-A37C-09) from TCGA case TCGA-R6-A8W5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.0 years (21,917 days).
Specimen TCGA-R6-A8W5-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c9b86b4-2d1e-4276-9de9-abf215617baa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A8W5-10A (Blood Derived Normal), aliquot TCGA-R6-A8W5-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e80aab17-afb7-47a5-94d0-60991937917a

The open-access MAF lists 98 somatic variants for this specimen: 69 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 26, Nonsense Mutation 6, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, RNA 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB1 | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.515); catalogued as rs374047873, COSV60100757; called by muse, mutect2, varscan2
- ANK2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV52157384; called by muse, mutect2, varscan2
- APOBEC2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as rs144963628; called by muse, mutect2, varscan2
- ARHGAP39 | c.2528C>T p.A843V (on ENST00000276826 / NM_001308208.2; = p.A874V on NM_025251.2) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1334771312, COSV52769615; called by muse, mutect2
- ATMIN | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100214538; called by muse, mutect2, varscan2
- ATP10A | c.3896T>G p.V1299G | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63519647; called by muse, mutect2
- C16orf78 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs139737719; called by muse, mutect2, varscan2
- COL18A1 | c.2043G>A p.T681= (on ENST00000359759 / NM_130444.3; = p.T446= on NM_030582.4) | Splice Region (SNP) | VAF 31/77 reads (40%) | catalogued as rs527870177, COSV62705285; called by muse, mutect2, varscan2
- CYP7B1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59595296; called by muse, mutect2, varscan2
- DNAH5 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775816222, COSV54250857; called by muse, mutect2, varscan2
- DPP10 | c.442-1G>T p.X148_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as rs758635933; called by muse, mutect2, varscan2
- FLG | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1169418418; called by muse, varscan2
- GLYATL2 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV54849987; called by muse, mutect2, varscan2
- LRRC49 | c.1778G>A p.S593N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1432291959, COSV99538226; called by muse, mutect2, varscan2
- MSH4 | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54204899, COSV54210661; called by muse, mutect2
- NDST4 | c.632A>T p.E211V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV52116304, COSV99996607; called by muse, mutect2, varscan2
- OPCML | c.1025T>C p.F342S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV59448338; called by muse, mutect2, varscan2
- OSBPL6 | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs372381868; called by muse, mutect2, varscan2
- PCDHB1 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.438); catalogued as COSV60631937; called by muse, mutect2, varscan2
- PLCB3 | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV54187836; called by muse, varscan2
- PRKN | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs751485437; called by muse, mutect2, varscan2
- PROX1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as rs778287412, COSV99800432; called by muse, mutect2, varscan2
- PTPRD | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as rs142009246; called by muse, mutect2, varscan2
- PWWP3B | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.808); catalogued as COSV61802092; called by muse, mutect2, varscan2
- RCN3 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs769222993, COSV99571174; called by muse, mutect2, varscan2
- SERPINB10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV53072745; called by muse, mutect2, varscan2
- SLC22A11 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs757063285; called by muse, mutect2, varscan2
- SLITRK4 | c.2054C>A p.A685D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs782329018; called by muse, mutect2, varscan2
- TMC6 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1042301977; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.182A>T p.K61M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64423286; called by muse, mutect2, varscan2
- TRIM9 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs1260763850, COSV53625137; called by muse, mutect2, varscan2
- TTBK1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs745618169, COSV52491503; called by muse, mutect2, varscan2
- WASHC4 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765881333, COSV59891504; called by muse, mutect2
- ZNF586 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | catalogued as COSV101656724; called by muse, mutect2, varscan2
- ACACA | c.5147T>C p.V1716A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- AFF1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ATP10B | c.3545A>T p.K1182M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); called by muse, mutect2
- CARF | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CCT5 | c.934C>A p.H312N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK2 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CIC | c.2033del p.P678Lfs*50 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- CPNE8 | c.1669A>C p.T557P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRB2 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.104A>C p.D35A | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM135B | c.1921T>A p.C641S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FBXW7 | c.1417dup p.R473Kfs*4 (on ENST00000281708 / NM_001349798.2; = p.R393Kfs*4 on NM_018315.5) | Frame Shift Ins (INS) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- FBXW7 | c.469_485del p.L157Yfs*15 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- FLG | c.213_217dup p.E73Afs*6 | Frame Shift Ins (INS) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- HSD17B11 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IQGAP3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRTAP24-1 | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LAMC2 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTA4H | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- MEX3B | c.1396G>T p.G466* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MFHAS1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2
- NOLC1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- OR4X2 | c.283T>G p.F95V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PCDH1 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO1 | c.3817C>T p.P1273S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- RYR2 | c.6826A>C p.S2276R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCN3A | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SULT1C3 | c.432C>G p.C144W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SYNJ2 | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- TGIF2LX | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TOPBP1 | c.4049A>G p.E1350G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WFDC9 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZBED9 | c.1769A>C p.E590A | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF544 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C11orf87 | c.390G>T p.R130= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- DOK4 | c.840C>T p.I280= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1359765983, COSV54672456; called by muse, mutect2
- ENTPD4 | c.1683C>A p.V561= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV100652852; called by muse, mutect2
- GOLGA7B | c.84C>T p.S28= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs764761052, COSV65428662; called by muse, mutect2, varscan2
- HERC1 | c.8058T>C p.S2686= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs775126676; called by muse, mutect2, varscan2
- HK3 | c.1569C>A p.P523= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- IRS2 | c.1782G>T p.S594= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101019075; called by muse, mutect2, varscan2
- LDHD | c.1452C>T p.G484= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs752729893, COSV55580034; called by muse, mutect2, varscan2
- LRRTM3 | c.615C>T p.I205= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV63669798; called by muse, mutect2, varscan2
- MAP3K9 | c.1794G>A p.T598= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs146227942; called by muse, mutect2, varscan2
- MCTP1 | c.1746C>A p.V582= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- NRP2 | c.2499C>T p.Y833= (on ENST00000360409 / NM_201266.2; = p.Y828= on NM_003872.3) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs776279335, COSV63375801, COSV63377586; called by muse, varscan2
- OR2A12 | c.932G>A p.*311= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- OR2L2 | c.291G>A p.G97= | Silent (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3801G>A p.T1267= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs747752702; called by muse, varscan2
- PRIM1 | c.1204C>T p.L402= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1456580137; called by mutect2, varscan2
- PTPRN | c.102C>T p.A34= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV55347417; called by muse, mutect2, varscan2
- RIMKLB | c.1074G>T p.T358= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs201727444; called by muse, mutect2, varscan2
- SFMBT1 | c.231G>A p.E77= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- SLC25A18 | c.825G>A p.E275= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1368102022, COSV53656928; called by muse, mutect2, varscan2
- SMR3B | c.120T>G p.P40= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- TECRL | c.558T>G p.A186= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- THNSL2 | c.1017C>T p.A339= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- UBE2D1 | c.291G>T p.L97= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- ULK4 | c.2247A>G p.R749= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- VPS13B | c.10275G>A p.P3425= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs151315104; called by muse, mutect2, varscan2
- CLCA3P | n.279A>G | RNA (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- CXCL12 | c.267-2607A>G | Intron (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- TMEM107 | c.*715C>G | 3'UTR (SNP) | VAF 7/20 reads (35%) | catalogued as rs150885627; called by muse, mutect2, varscan2
